Somatic mutation profile of tumor specimen 0DI6KZ from CCDI case PBBVDY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 7.2 years (2,633 days).
Specimen 0DI6KZ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2dbada12-e1d1-4a12-bc76-2fdb806f27a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI6KH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3be7474a-e175-48f1-a4c0-cbdf55e3c5a5

The open-access MAF lists 15 somatic variants for this specimen: 13 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 10, Silent 2, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C3 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 433/1077 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV63551114; called by muse, mutect2, varscan2
- INPP5F | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 211/602 reads (35%) | catalogued as rs746400005; called by muse, mutect2, varscan2
- KMT2C | c.11548C>T p.R3850* | Nonsense Mutation (SNP) | VAF 454/1098 reads (41%) | catalogued as COSV51426966; called by muse, mutect2, varscan2
- KMT2C | c.401G>A p.C134Y | Missense Mutation (SNP) | VAF 199/565 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51446263; called by muse, mutect2, varscan2
- LATS2 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 320/798 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.339); catalogued as COSV101231572; called by muse, mutect2, varscan2
- MUC16 | c.28360G>T p.G9454W | Missense Mutation (SNP) | VAF 70/907 reads (8%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.926); catalogued as rs559963047; called by muse, mutect2
- RAVER1 | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 187/488 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs749257587, COSV99532696; called by muse, mutect2, varscan2
- TGM2 | c.103C>T p.R35W | Missense Mutation (SNP) | VAF 242/639 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771987793, COSV63931601; called by muse, mutect2, varscan2
- AGTR1 | c.-46T>G | Splice Region (SNP) | VAF 275/715 reads (38%) | called by muse, mutect2, varscan2
- CCDC168 | c.6442G>C p.G2148R | Missense Mutation (SNP) | VAF 136/936 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- FAM120A | c.375T>G p.H125Q | Missense Mutation (SNP) | VAF 356/850 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- GTF2A1 | c.598C>A p.P200T | Missense Mutation (SNP) | VAF 256/637 reads (40%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TTLL5 | c.3749C>T p.S1250F | Missense Mutation (SNP) | VAF 211/554 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- MARCOL | c.75C>A p.T25= | Silent (SNP) | VAF 183/716 reads (26%) | called by mutect2, varscan2
- RICTOR | c.411G>A p.Q137= | Silent (SNP) | VAF 45/1424 reads (3%) | called by muse, mutect2
